Somatic mutation profile of tumor specimen ALCH-B015-TTP1-A (aliquot ALCH-B015-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-B015, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 60.9 years (22,240 days).
Specimen ALCH-B015-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2562f794-29d4-4205-9120-ec1000d0dfc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B015-NB1-A (Blood Derived Normal), aliquot ALCH-B015-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/add1254c-3307-4e55-9d67-e2c6e2a1feb4

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Splice Region 2, In Frame Del 1, Translation Start Site 1, Frame Shift Del 1, Splice Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 157/443 reads (35%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by pindel, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 156/325 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.5160+1G>A p.X1720_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as rs45517399, CS010586, CS091151; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CALN1 | c.643C>T p.R215W (on ENST00000329008 / NM_001017440.3; = p.R257W on NM_031468.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1562776430, COSV61119545; called by muse, mutect2, varscan2
- CALR3 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 52/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54170986; called by muse, mutect2, varscan2
- CSMD3 | c.8973C>T p.I2991= (on ENST00000297405 / NM_001363185.1; = p.I2822= on NM_052900.3) | Splice Region (SNP) | VAF 16/458 reads (3%) | catalogued as COSV52323108; called by muse, mutect2
- EGFR | c.2264C>G p.A755G | Missense Mutation (SNP) | VAF 233/500 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV51783384, COSV51786456; called by muse, varscan2
- FAM71B | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs754739653, COSV57230151; called by muse, mutect2, varscan2
- FNDC1 | c.2167C>A p.H723N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV51932484, COSV51933117; called by muse, mutect2
- FNDC1 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV51940197, COSV51942921, COSV99794521; called by muse, mutect2, varscan2
- ISM2 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761314866, COSV53633757, COSV53636934; called by muse, mutect2, varscan2
- KY | c.198C>T p.H66= | Splice Region (SNP) | VAF 21/286 reads (7%) | catalogued as rs747530241, COSV71016755; called by muse, mutect2
- LAX1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs766817372, COSV65848765; called by muse, mutect2
- MET | c.2746T>A p.S916T | Missense Mutation (SNP) | VAF 99/777 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV59260182; called by muse, mutect2, varscan2
- RELN | c.8423C>T p.S2808F | Missense Mutation (SNP) | VAF 28/593 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100634040; called by muse, mutect2
- SIRPA | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.399); catalogued as rs756656814; called by muse, mutect2, varscan2
- SPAG16 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs375638696; called by muse, mutect2
- SPATA16 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 12/420 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100651474; called by muse, mutect2
- TENM2 | c.3088A>G p.I1030V (on ENST00000518659 / NM_001122679.2; = p.I798V on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757229073; called by muse, mutect2, varscan2
- VWC2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61483258, COSV61484176; called by muse, mutect2, varscan2
- WNT7A | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs139562589, COSV53201603; called by muse, mutect2, varscan2
- ZNF512B | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765351969; called by mutect2, varscan2
- ANKRD34C | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 8/237 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BIRC6 | c.9437A>C p.K3146T | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2
- BRWD3 | c.4466C>A p.A1489D | Missense Mutation (SNP) | VAF 30/738 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2
- FLOT2 | c.989T>G p.I330S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GATA3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- KCNB2 | c.2575A>G p.T859A | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.034); called by muse, mutect2
- KRT31 | c.1126A>G p.N376D | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.098); called by muse, mutect2
- LRP1B | c.11241T>G p.D3747E | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RRP12 | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLITRK1 | c.1379A>G p.Q460R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- SPAG17 | c.2675C>G p.A892G | Missense Mutation (SNP) | VAF 70/559 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THOC2 | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNKS1BP1 | c.3306del p.F1102Lfs*31 | Frame Shift Del (DEL) | VAF 33/148 reads (22%) | called by mutect2, pindel, varscan2
- TTC37 | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 20/543 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- USP7 | c.1849C>G p.Q617E | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ZNF721 | c.572G>C p.G191A (on ENST00000338977; = p.G203A on NM_133474.4) | Missense Mutation (SNP) | VAF 27/618 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); called by muse, mutect2
- ATP9B | c.2970G>A p.E990= | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as rs1459249089; called by muse, mutect2
- BIRC6 | c.3705T>C p.I1235= | Silent (SNP) | VAF 79/278 reads (28%) | called by muse, mutect2, varscan2
- CENPE | c.1554A>T p.R518= | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- KLHL3 | c.1398G>A p.A466= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as rs1399725679, COSV59054652; called by muse, mutect2
- LRP1B | c.3222T>C p.D1074= | Silent (SNP) | VAF 24/338 reads (7%) | catalogued as rs752150869; called by muse, mutect2
- MMEL1 | c.1569C>T p.D523= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs145790318; called by muse, mutect2, varscan2
- MYH7 | c.1656G>T p.L552= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV62516657; called by muse, mutect2
- PCLO | c.3681A>T p.I1227= | Silent (SNP) | VAF 40/662 reads (6%) | called by muse, mutect2
- PSG6 | c.195C>T p.Y65= | Silent (SNP) | VAF 18/296 reads (6%) | catalogued as rs879046556; called by muse, mutect2
- RNF121 | c.483C>G p.L161= | Silent (SNP) | VAF 382/1306 reads (29%) | catalogued as COSV62317282; called by muse, varscan2
- TIGD4 | c.933A>G p.L311= | Silent (SNP) | VAF 24/197 reads (12%) | catalogued as rs527498419; called by muse, mutect2, varscan2
- FRMD8P1 | n.659G>A | RNA (SNP) | VAF 6/48 reads (13%) | catalogued as rs1319535948; called by muse, mutect2, varscan2
- MAP3K7CL | c.370+16570C>T | Intron (SNP) | VAF 31/447 reads (7%) | catalogued as rs750242641; called by muse, mutect2
